Somatic mutation profile of tumor specimen C3L-01158-01 (aliquot CPT0171630020) from CPTAC case C3L-01158, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 69.1 years (25,247 days).
Specimen C3L-01158-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d126d61-9e1a-4994-ab95-2f52a19c3695.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01158-31 (Blood Derived Normal), aliquot CPT0171560002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d8312c0-f500-4d88-a39a-e5c490480471

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: RNA 2, Silent 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 133/2057 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CDH11 | c.426G>A p.P142= | Silent (SNP) | VAF 61/1828 reads (3%) | catalogued as rs758854974, COSV51776352; called by muse, mutect2
- POLD1 | c.2874G>C p.L958= | Silent (SNP) | VAF 32/1170 reads (3%) | called by muse, mutect2
- ADGRE4P | n.490A>G | RNA (SNP) | VAF 26/1026 reads (3%) | called by muse, mutect2
- OR2W5 | n.835C>T | RNA (SNP) | VAF 46/1444 reads (3%) | called by muse, mutect2
